Gene-level copy-number profile of tumor specimen ALCH-AFFM-TTP1-A from ALCHEMIST case ALCH-AFFM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,110 days).
Specimen ALCH-AFFM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f49ae28b-95a1-46d8-b1f9-156b8d7394b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/0fe0e2aa-f872-44b7-94be-924839d233b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 609; copy number 1: 1,327; copy number 2: 9,105; copy number 3: 23,785; copy number 4: 13,534; copy number 5: 5,917; copy number 6: 2,992; copy number 7: 1,071; copy number 8: 380; copy number 10: 5; copy number 11: 86; copy number 13: 92.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,125,216–86,125,287, 1 gene: AC107024.1.
- chr9:14,068,932–14,722,733, 11 genes: ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1.
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:23,500,691–26,786,874, 18 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2.
- chr9:36,833,269–37,384,434, 16 genes (within-gene range 0–4): PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627.
- chr9:37,879,400–37,904,353, 2 genes (within-gene range 0–3): SLC25A51, TMX2P1.
- chr9:37,936,707–39,288,315, 28 genes (within-gene range 0–3): RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P.
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–2): BX664615.2.
- chr9:41,292,887–41,355,538, 3 genes: MYO5BP1, AL354718.2, CDRT15P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,634 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,683,976–28,751,722, 2 genes, copy number 8 (within-gene range 6–8): RNA5SP89, AC092164.1.
- chr2:31,651,381–32,821,051, 26 genes, copy number 8: AL133247.2, LINC01946, KRT18P52, AK2P2, AL121652.1, MEMO1, DPY30, AL121655.1, SPAST, AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1, BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765.
- chr2:70,257,386–70,302,090, 4 genes, copy number 8: PCYOX1, SNRPG, FAM136A, AC022201.2.
- chr3:87,594,838–87,793,629, 4 genes, copy number 10: APOOP2, PSMC1P6, AC108749.1, RNU6-873P.
- chr3:87,910,220–87,910,345, 1 gene, copy number 10: RNU6ATAC6P.
- chr3:169,709,295–170,418,615, 30 genes, copy number 7: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr5:126,751,963–126,837,020, 3 genes, copy number 7: LMNB1-DT, RNU6-752P, LMNB1.
- chr7:81,946,444–88,202,889, 46 genes, copy number 8: CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22.
- chr8:143,065,915–143,160,711, 3 genes, copy number 8: AC083982.1, LY6L, LY6H.
- chr9:30,388,935–34,982,544, 130 genes, copy number 8–11 (broad region; genes not listed).
- chr9:36,190,856–36,487,548, 5 genes, copy number 13: CLTA, GNE, RNU4-53P, HMGB3P24, RNF38.
- chr10:11,823,339–12,169,961, 8 genes, copy number 8 (within-gene range 6–8): PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK.
- chr11:77,066,961–78,582,156, 44 genes, copy number 8: CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr17:21,614,487–32,906,584, 336 genes, copy number 7–8 (broad region; genes not listed).
- chr17:34,927,859–51,336,240, 851 genes, copy number 7 (broad region; genes not listed).
- chr17:73,163,035–76,384,521, 138 genes, copy number 11–13 (within-gene range 2–13) (broad region; genes not listed).
- chr19:20,295,089–20,331,517, 3 genes, copy number 11 (within-gene range 3–11): AC078899.4, BNIP3P19, AC078899.5.

Autosomal genes at a single copy (total copy number 1): 709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
